TCGA case TCGA-19-0962 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Case Western. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/20a83eb1-466d-4f85-921a-cb8beea8eabe

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 77 years; Vital status: Dead; Days to death: 20 days.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 77.7 years (28,382 days); Year of diagnosis: 2008; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Karnofsky performance status: 40; Timepoint: Prior to Adjuvant Therapy.
- Follow-up contacts recording only the day: day 13, day 20.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-19-0962-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.1; Intermediate dimension: 0.7; Shortest dimension: 0.6.
  Slide TCGA-19-0962-01B-01-BS1: Section location: Bottom; Percent tumor cells: 30; Percent tumor nuclei: 100; Percent normal cells: 10; Percent necrosis: 40; Percent stromal cells: 30.
  Slide TCGA-19-0962-01B-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
- Sample TCGA-19-0962-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-19-0962-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Performance status timing: Pre-Adjuvant Therapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 20 days; disease-specific survival: event status not recorded, 20 days; progression-free interval: no event (censored), 20 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-19-0962-01): tumor purity 0.77, ploidy 1.94, whole-genome doublings 0 (call status: legacy_call).
